Somatic mutation profile of tumor specimen ALCH-ACGT-TTP1-A (aliquot ALCH-ACGT-TTP1-A-3-0-D-A49Q-36) from ALCHEMIST case ALCH-ACGT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.0 years (21,919 days).
Specimen ALCH-ACGT-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ff20b55-9ae1-4124-a8c2-448a4f470255.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ACGT-NB1-A (Blood Derived Normal), aliquot ALCH-ACGT-NB1-A-1-0-D-A49Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0daedd44-a3d8-400d-bd76-2baf0426a472

The open-access MAF lists 47 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 11, Intron 2, In Frame Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 67/225 reads (30%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 98/288 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARHGAP39 | c.2528C>G p.A843G (on ENST00000276826 / NM_001308208.2; = p.A874G on NM_025251.2) | Missense Mutation (SNP) | VAF 48/290 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV52769615; called by muse, mutect2, varscan2
- C11orf91 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 133/438 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.96); catalogued as rs1471676612; called by muse, mutect2, varscan2
- DCLK3 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1343382801; called by muse, mutect2
- EVL | c.245G>A p.R82Q (on ENST00000402714 / NM_001330221.2; = p.R84Q on NM_016337.3) | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1567016267, COSV67376680; called by muse, mutect2
- FAM166C | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.467); catalogued as rs775521325; called by muse, mutect2, varscan2
- GAGE1 | c.358A>G p.T120A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs782279724, COSV67747457; called by muse, varscan2
- NUDC | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV57671267; called by muse, mutect2, varscan2
- OTC | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as CM1512785, CM950879, COSV50000745; called by muse, mutect2, varscan2
- PCDHGA1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 216/725 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as rs1344067004, COSV65298800; called by muse, mutect2, varscan2
- PKD1L2 | c.2338A>G p.I780V | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs752504784; called by muse, mutect2, varscan2
- SYT12 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs199773761; called by muse, mutect2, varscan2
- TENM2 | c.7321G>A p.D2441N (on ENST00000518659 / NM_001122679.2; = p.D2202N on NM_001080428.3) | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); catalogued as rs1224907195; called by muse, mutect2
- VRTN | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 82/369 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373225215, COSV56439428; called by muse, mutect2, varscan2
- CASC3 | c.1133A>G p.E378G | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDHR1 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 91/481 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- EDC4 | c.2929A>G p.T977A | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHBP1L1 | c.1270G>T p.V424L | Missense Mutation (SNP) | VAF 116/293 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FAM118A | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by mutect2, varscan2
- MAP3K1 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MGAM2 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- MUC17 | c.3181A>G p.T1061A | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRXN1 | c.184A>T p.S62C | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR13C5 | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OR4C6 | c.479T>A p.F160Y | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PIK3C2G | c.3273T>G p.I1091M (on ENST00000676171; = p.I1050M on NM_004570.5) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRPF8 | c.2818A>T p.I940F | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- RPS6KA1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 139/469 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SIGLEC1 | c.3854C>A p.A1285D | Missense Mutation (SNP) | VAF 109/415 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TRAF6 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX4 | c.10636C>G p.P3546A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- CACNG7 | c.129G>A p.P43= | Silent (SNP) | VAF 66/195 reads (34%) | catalogued as rs376239971; called by muse, mutect2, varscan2
- DLGAP1 | c.1566C>T p.T522= | Silent (SNP) | VAF 79/290 reads (27%) | catalogued as rs751407164, COSV59811981; called by muse, mutect2, varscan2
- KIAA1210 | c.22C>A p.R8= | Silent (SNP) | VAF 45/106 reads (42%) | called by muse, mutect2
- LRP5 | c.393C>G p.R131= | Silent (SNP) | VAF 176/832 reads (21%) | called by muse, mutect2, varscan2
- MLX | c.810C>T p.F270= | Silent (SNP) | VAF 28/232 reads (12%) | called by muse, mutect2, varscan2
- OR2B11 | c.523C>A p.R175= | Silent (SNP) | VAF 38/426 reads (9%) | catalogued as rs1216004925, COSV59509260, COSV59511813; called by muse, mutect2
- OR52N2 | c.489C>T p.L163= | Silent (SNP) | VAF 7/49 reads (14%) | called by mutect2, varscan2
- OTOG | c.7326G>A p.V2442= | Silent (SNP) | VAF 39/189 reads (21%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1359G>A p.P453= | Silent (SNP) | VAF 292/784 reads (37%) | catalogued as rs762381127, COSV100971420; called by muse, mutect2, varscan2
- PPIAL4G | c.12C>T p.S4= | Silent (SNP) | VAF 143/260 reads (55%) | catalogued as rs1553321612, COSV70087327; called by muse, mutect2, varscan2
- TAS1R3 | c.2502T>C p.P834= | Silent (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- COL5A1 | c.3528+20C>T | Intron (SNP) | VAF 22/137 reads (16%) | catalogued as rs953439461; called by muse, mutect2, varscan2
- HLCS | c.-292G>T | 5'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 12/210 reads (6%) | catalogued as rs910081914; called by muse, mutect2
- XIAP | c.*5652C>T | 3'UTR (SNP) | VAF 6/60 reads (10%) | catalogued as rs200661683; called by mutect2, varscan2
